Surgical pathology report (de-identified scan), TCGA case TCGA-69-8255, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-69-8255-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

Patient Age/Sex [REDACTED] M

SPECIMEN SUBMITTED:

Part A: POSTERIOR SEGMENT RIGHT
UPPER LOBE

Part B: LEVEL 10 R

Final Diagnosis

1. Right lung, upper lobe, wedge excision (A) Adenocarcinoma, solid predominant (40%) with acinar (40%), and lepidic (20%) patterns.
- Mild centrilobular emphysema.
- See comment.
2. Lymph node, level 10R, excision (B) Hyalinized lymph node, negative for neoplasm.

Diagnosis Comment:

1. The tumor measures 1.6 cm in greatest dimension. No invasion into or through the pleural is seen. The parenchymal margin of excision is negative for neoplasm. Further studies to define the origin of this adenocarcinoma will be performed and the results of those studies reported as an addendum.

Intraoperative Diagnosis:

- A. Adenocarcinoma. Margin negative.

Clinical Diagnosis:

LUNG NODULES

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Gross Description:

A. Received fresh for frozen section diagnosis labeled "posterior segment right upper lobe" is a wedge of lung measuring 14.8 x 5.2 x 2.7 cm, and weighing 39.1 grams. A staple line is present and inked orange. The pleural surface displays a puckered area measuring 1.2 x 0.8 cm and is located 3.2 cm from the orange inked parenchymal margin. The remainder of the pleural surface is smooth and glistening. The puckered area is inked blue. Upon sectioning, a stellate tan-gray firm nodule is identified in the puckered region measuring 1.6 x 1.2 x 1.0 cm, and extending within 2.7 cm of the parenchymal line of resection and appears to extend into, but not through the pleura. The remainder of the parenchyma is unremarkable. Other masses, lesions, nodules are not present. The mass is totally submitted. The nodule is totally submitted as follows: A1 nodule with closest pleural involvement, A2 perpendicular line of resection representative section, A3-A5 nodule with pleural surface, A6 remainder of nodule totally submitted, A7 additional representative section of parenchymal margin, A8 representative section of apparent uninvolved tissue.

B. Received fresh is a tan-black nodule resembling lymph node measuring 0.4 x 0.3 x 0.2 cm. The specimen is not sectioned. Totally submitted in one cassette.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file 8d7b415a-350c-4319-8adb-9ba155166f73 (TCGA-69-8255.D807CBCD-B72D-47F5-975B-347782728E94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).